Somatic mutation profile of tumor specimen TCGA-DM-A28C-01A (aliquot TCGA-DM-A28C-01A-11D-A16V-10) from TCGA case TCGA-DM-A28C, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.1 years (27,073 days).
Specimen TCGA-DM-A28C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 331151ad-436b-4bb3-8138-7599a64a2531.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28C-10A (Blood Derived Normal), aliquot TCGA-DM-A28C-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e2e5172-6299-47bd-8520-9429baec280a

The open-access MAF lists 109 somatic variants for this specimen: 86 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 22, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 2, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 65/80 reads (81%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 77/176 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 88/213 reads (41%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, varscan2
- ADAMTS16 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV56976258; called by muse, mutect2, varscan2
- ADAMTS9 | c.5651del p.S1884Ffs*2 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as COSV55782177; called by mutect2, pindel, varscan2
- ADGRL3 | c.2763C>A p.H921Q (on ENST00000506720 / NM_001322402.2; = p.H853Q on NM_015236.6) | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768845959, COSV72230711; called by muse, mutect2, varscan2
- AMBRA1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54054827; called by muse, mutect2, varscan2
- AMBRA1 | c.574G>T p.G192* | Nonsense Mutation (SNP) | VAF 41/104 reads (39%) | catalogued as COSV54054839; called by muse, mutect2, varscan2
- ARHGEF6 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.009); catalogued as COSV51691511; called by muse, mutect2, varscan2
- ARSI | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.11); catalogued as COSV60817597; called by muse, mutect2, varscan2
- ASCC3 | c.3552G>A p.M1184I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1291289896, COSV100225260; called by muse, mutect2, varscan2
- CCDC18 | c.1804G>C p.A602P (on ENST00000343253 / NM_001306076.1; = p.A603P on NM_206886.4) | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV100159728, COSV58143901; called by muse, mutect2, varscan2
- CCN3 | c.481G>C p.V161L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV52384055; called by muse, mutect2, varscan2
- CD1E | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV63770534, COSV63771210; called by muse, mutect2, varscan2
- CD84 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 103/489 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907105760, COSV60866855; called by muse, mutect2, varscan2
- CD93 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as COSV55664286, COSV55665625; called by muse, mutect2, varscan2
- CDH9 | c.1486G>C p.V496L | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.817); catalogued as COSV50293532; called by muse, mutect2, varscan2
- CEP350 | c.2681_2686del p.Q894_M896delinsL | In Frame Del (DEL) | VAF 59/80 reads (74%) | catalogued as COSV62603329; called by mutect2, pindel, varscan2
- CHFR | c.1186C>T p.R396W (on ENST00000432561 / NM_001161345.1; = p.R355W on NM_018223.2) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs920205326, COSV57174795; called by muse, mutect2, varscan2
- COQ8B | c.1163G>A p.G388D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754444229, COSV54687174; called by muse, mutect2, varscan2
- CPS1 | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs757451824, COSV51801952; called by muse, mutect2, varscan2
- DICER1 | c.5113G>C p.E1705Q | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- DLG5 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748210887, COSV64948254; called by muse, mutect2, varscan2
- EFEMP1 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV62616357; called by muse, mutect2, varscan2
- EIF3A | c.3140G>A p.G1047E | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV64961604; called by muse, mutect2, varscan2
- ENTPD2 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV57075508; called by muse, mutect2, varscan2
- EVC2 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs766569633, COSV60389383; called by muse, mutect2, varscan2
- FAM118B | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV64157125; called by muse, mutect2, varscan2
- FAM163B | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs759555682; called by muse, mutect2, varscan2
- FAT4 | c.3431C>A p.P1144Q | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV101271947; called by muse, mutect2, varscan2
- FBXO4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV55852382; called by muse, mutect2, varscan2
- FCRLA | c.444C>A p.N148K (on ENST00000367959; = p.N125K on NM_032738.4) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV52684596; called by muse, mutect2, varscan2
- GPNMB | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs145407985; called by muse, mutect2, varscan2
- H4C9 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); catalogued as rs768322550, COSV100574867; called by muse, mutect2, varscan2
- HERC2 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55326230; called by muse, mutect2, varscan2
- INHBA | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54220417; called by muse, mutect2, varscan2
- KMT2C | c.12779C>G p.S4260C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV51517576; called by muse, mutect2, varscan2
- LOXL4 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996964551, COSV53257007; called by muse, mutect2, varscan2
- MAGEE2 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750254417, COSV100973005; called by muse, mutect2, varscan2
- MCTP2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs139457907; called by muse, mutect2, varscan2
- MDN1 | c.1074G>C p.Q358H | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV65522477; called by muse, mutect2, varscan2
- MTCH1 | c.1068G>T p.W356C (on ENST00000373627 / NM_001271641.1; = p.W339C on NM_014341.2) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV65320501, COSV65320671; called by muse, mutect2, varscan2
- MYH7 | c.5071G>A p.V1691M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs45464193, CM031282, COSV62518813, COSV62521627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- N4BP2 | c.1277del p.P426Qfs*6 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | catalogued as COSV54701811; called by mutect2, pindel, varscan2
- NELL2 | c.1563C>A p.C521* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as rs529662932, COSV100418807; called by muse, mutect2, varscan2
- NFASC | c.2452G>A p.G818S (on ENST00000339876 / NM_001378329.1; = p.G814S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457220793, COSV58366673; called by muse, mutect2, varscan2
- NFXL1 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV61199184; called by muse, mutect2, varscan2
- NRXN3 | c.3079C>T p.R1027C (on ENST00000335750 / NM_001330195.2; = p.R654C on NM_004796.6) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140301017; called by muse, mutect2, varscan2
- NSD1 | c.2796C>G p.N932K | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.212); catalogued as COSV61776972; called by muse, mutect2, varscan2
- OBSCN | c.4412C>T p.T1471M | Missense Mutation (SNP) | VAF 138/210 reads (66%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); catalogued as rs771717556, COSV52748407; called by muse, mutect2, varscan2
- OR4K1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs755426984, COSV53459544, COSV99579075; called by muse, mutect2, varscan2
- PALMD | c.751T>C p.S251P | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs776443928, COSV54164734; called by muse, mutect2, varscan2
- PCDHA3 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100793723, COSV63542265; called by muse, mutect2, varscan2
- PPP4R4 | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs1487405347, COSV58551644, COSV58555022; called by muse, mutect2, varscan2
- PPP6R3 | c.1278+1G>A p.X426_splice (on ENST00000393800 / NM_001352375.2; = p.X375_splice on NM_018312.5) | Splice Site (SNP) | VAF 45/113 reads (40%) | catalogued as COSV55727434; called by muse, mutect2, varscan2
- PSG4 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs189743457, COSV54936141; called by muse, mutect2, varscan2
- PTCHD4 | c.1433C>A p.S478Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59785782, COSV59791733; called by muse, mutect2, varscan2
- PXDNL | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV62478104, COSV62493633; called by muse, mutect2, varscan2
- RASAL3 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs775451877, COSV54604421; called by muse, mutect2, varscan2
- RBCK1 | c.544G>A p.G182R (on ENST00000356286 / NM_031229.4; = p.G140R on NM_006462.6) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs1366170905, COSV100675762, COSV62292734; called by muse, mutect2, varscan2
- RTP1 | c.695C>A p.S232* | Nonsense Mutation (SNP) | VAF 71/148 reads (48%) | catalogued as COSV56618574; called by muse, mutect2, varscan2
- SEZ6L | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961405; called by muse, mutect2, varscan2
- SIPA1L1 | c.1535G>C p.G512A | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62170568; called by muse, mutect2, varscan2
- SLC25A39 | c.307C>T p.R103C (on ENST00000377095 / NM_001143780.3; = p.R95C on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs1430593963, COSV56587587; called by muse, mutect2, varscan2
- SLIT3 | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV60610820; called by muse, mutect2, varscan2
- SMC6 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs748740216, COSV61173724; called by muse, mutect2, varscan2
- SOX2 | c.201C>A p.H67Q | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57621701; called by muse, mutect2, varscan2
- SPATC1L | c.718G>A p.G240S (on ENST00000291672 / NM_001142854.2; = p.G86S on NM_032261.5) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV52433366; called by muse, mutect2, varscan2
- SYNE1 | c.4836C>G p.F1612L (on ENST00000367255 / NM_182961.4; = p.F1619L on NM_033071.3) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99554279; called by muse, mutect2, varscan2
- TAF1L | c.1318A>G p.I440V | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54262599; called by muse, mutect2, varscan2
- TBX19 | c.1127del p.S376Tfs*13 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as COSV100892392, COSV63197612; called by mutect2, pindel, varscan2
- TLK2 | c.972A>T p.Q324H | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV58300645; called by muse, mutect2, varscan2
- TNK1 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61170912; called by muse, mutect2, varscan2
- TPRKB | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs1383562357, COSV55541288; called by muse, mutect2, varscan2
- VNN3 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs936683317, COSV51591244; called by muse, varscan2
- VPS36 | c.499dup p.R167Kfs*5 | Frame Shift Ins (INS) | VAF 37/108 reads (34%) | catalogued as rs777713470; called by mutect2, pindel, varscan2
- XIRP2 | c.26G>A p.R9H (on ENST00000628543; = p.R184H on NM_152381.6) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs375141738, COSV54703785; called by muse, mutect2, varscan2
- ZC3H11A | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 193/276 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); catalogued as COSV59746888; called by muse, mutect2, varscan2
- ZNF208 | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1231669129, COSV68106979; called by muse, mutect2, varscan2
- ZNF395 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0.342); catalogued as COSV100733865; called by muse, mutect2, varscan2
- ZNF646 | c.4073G>A p.R1358Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.375); catalogued as rs747370791, COSV54924049; called by muse, varscan2
- ZNF804A | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 48/135 reads (36%) | catalogued as rs772974941, COSV56437401, COSV56474195; called by muse, mutect2, varscan2
- FSTL5 | c.45T>G p.F15L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- IARS1 | c.874dup p.L292Pfs*3 | Frame Shift Ins (INS) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- TGIF1 | c.11_26del p.P4Hfs*70 (on ENST00000330513 / NM_001374396.1; = p.P24Hfs*70 on NM_003244.4) | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- ABRAXAS2 | c.117C>T p.S39= | Silent (SNP) | VAF 140/345 reads (41%) | catalogued as rs769656894, COSV53717082; called by muse, mutect2, varscan2
- ACTL6B | c.219C>T p.H73= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV50515234; called by muse, mutect2, varscan2
- ADRA2B | c.294G>T p.S98= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV69787607, COSV69787622; called by muse, mutect2, varscan2
- C5 | c.1032C>T p.G344= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV99797148; called by muse, mutect2, varscan2
- FILIP1 | c.2634C>T p.N878= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as rs1176412579, COSV52727694; called by muse, mutect2, varscan2
- GJA8 | c.900C>T p.F300= | Silent (SNP) | VAF 44/62 reads (71%) | catalogued as rs782293999, COSV53789063; called by muse, mutect2, varscan2
- GRIA1 | c.1485C>T p.I495= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV53621108; called by muse, mutect2, varscan2
- HDLBP | c.3411C>T p.R1137= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs1300390903, COSV60496450; called by muse, mutect2, varscan2
- HOXB5 | c.9G>A p.S3= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV53313214; called by muse, mutect2, varscan2
- IGLL1 | c.621G>A p.V207= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV50769968; called by muse, mutect2, varscan2
- LPAR6 | c.660C>T p.S220= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV57309357; called by muse, mutect2, varscan2
- LRRC4B | c.1032C>T p.A344= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs764400653, COSV65349398; called by muse, mutect2, varscan2
- LTBP4 | c.3126G>A p.T1042= (on ENST00000308370 / NM_001042544.1; = p.T1005= on NM_003573.2) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs760559166, COSV52582388; called by muse, mutect2, varscan2
- MARS1 | c.267G>A p.A89= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs752312333, COSV100007104; called by muse, mutect2, varscan2
- MRPL10 | c.588G>A p.K196= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1338708438, COSV99136544; called by muse, mutect2
- MRPL34 | c.219G>A p.P73= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs199688783, COSV99395438; called by muse, mutect2, varscan2
- MUC16 | c.12510G>A p.S4170= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as rs377291046, COSV67454920; called by muse, mutect2, varscan2
- PCDHA13 | c.762C>T p.N254= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV56506833; called by muse, mutect2, varscan2
- SHROOM4 | c.798C>T p.P266= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as rs907277683, COSV56790066; called by muse, mutect2, varscan2
- SLIT2 | c.1470A>G p.E490= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV56574400; called by muse, mutect2, varscan2
- SMARCB1 | c.468C>T p.D156= (on ENST00000263121; = p.D202= on NM_003073.5) | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs727504163, COSV54096929, COSV54096943; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR17 | c.3834G>A p.T1278= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs145267415; called by muse, mutect2, varscan2
- SYNPO2L | c.773-2039G>A | Intron (SNP) | VAF 46/116 reads (40%) | catalogued as rs150707091; called by muse, mutect2, varscan2
